Somatic mutation profile of tumor specimen MMRF_2333_1_BM_CD138pos (aliquot MMRF_2333_1_BM_CD138pos_T3_KHS5U_K14027) from MMRF case MMRF_2333, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.0 years (29,589 days).
Specimen MMRF_2333_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81e0167b-698e-40c1-b7e5-4eff84ee05cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2333_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2333_1_PB_Whole_C1_KHS5U_K14026; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d915f405-d0a0-4b38-b36f-b914e83a5572

The open-access MAF lists 89 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 21, Silent 11, Intron 8, Frame Shift Del 5, RNA 2, Nonsense Mutation 2, 5'UTR 2, In Frame Del 1, 5'Flank 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IRF4 | c.368A>G p.K123R | Missense Mutation (SNP) | VAF 84/146 reads (58%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV66704523; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 56/125 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CNR2 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 66/138 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs528804725, COSV65694052; called by muse, mutect2
- CNTLN | c.1312C>T p.Q438* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV52076167; called by muse, mutect2, varscan2
- HPS1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as rs750207387; called by muse, mutect2, varscan2
- IGHV4-39 | c.86A>G p.Q29R | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs587664959; called by muse, mutect2, varscan2
- IGLV3-1 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 101/188 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.533); catalogued as rs534241034; called by mutect2, varscan2
- ITGAM | c.8T>G p.L3R | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs758554150; called by muse, mutect2, varscan2
- KAZN | c.1802G>A p.R601H | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1047832369; called by muse, mutect2, varscan2
- KCNG1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 100/202 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1477524044, COSV65367969; called by muse, mutect2, varscan2
- NLGN2 | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.637); catalogued as rs886509443; called by muse, mutect2, varscan2
- PDHB | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 119/233 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs1295648897; called by muse, mutect2, varscan2
- PIWIL4 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750655716; called by muse, mutect2, varscan2
- PRRC2C | c.767C>T p.P256L (on ENST00000367742; = p.P254L on NM_015172.4) | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs762204266; called by muse, mutect2, varscan2
- SLC6A6 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1364177670, COSV62650084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SVEP1 | c.5479A>C p.I1827L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV52835717; called by muse, mutect2, varscan2
- ZNF385B | c.617C>T p.T206M | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.927); catalogued as rs762051657, COSV61175899; called by muse, mutect2
- ZNF595 | c.446C>T p.T149I | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs782300741; called by muse, mutect2, varscan2
- ABHD17B | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- ADAM17 | c.114_131del p.L38_I44delinsF | In Frame Del (DEL) | VAF 28/54 reads (52%) | called by mutect2, pindel, varscan2
- CCDC38 | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 77/171 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- CD14 | c.605C>A p.S202Y | Missense Mutation (SNP) | VAF 83/150 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FASTKD1 | c.88C>A p.Q30K | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- IAH1 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 176/337 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KMT2A | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 101/212 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- KMT2D | c.8792del p.P2931Hfs*12 | Frame Shift Del (DEL) | VAF 41/102 reads (40%) | called by mutect2, pindel, varscan2
- LRG1 | c.36_51del p.G13Mfs*21 | Frame Shift Del (DEL) | VAF 43/111 reads (39%) | called by mutect2, pindel, varscan2
- MDK | c.-1G>C | Splice Region (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
- MLF1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- MYPN | c.3359_3360insT p.K1120Nfs*15 | Frame Shift Ins (INS) | VAF 68/127 reads (54%) | called by mutect2, pindel*, varscan2*
- NFE2L2 | c.592del p.Q198Sfs*23 | Frame Shift Del (DEL) | VAF 190/423 reads (45%) | called by mutect2, varscan2
- RARS1 | c.1647T>G p.N549K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- SIRT5 | c.115A>G p.S39G | Missense Mutation (SNP) | VAF 137/300 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC4A3 | c.3409C>A p.P1137T | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SUPT16H | c.1681G>A p.V561M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TBC1D16 | c.1248del p.K416Nfs*57 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- TNXB | c.9952del p.A3318Pfs*56 (on ENST00000647633; = p.A3071Pfs*56 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- TRMT9B | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 97/200 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TSHZ2 | c.446A>G p.N149S | Missense Mutation (SNP) | VAF 86/179 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE4A | c.2065C>G p.P689A (on ENST00000252108 / NM_001204077.2; = p.P696A on NM_004788.4) | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UPF1 | c.2587T>A p.F863I (on ENST00000599848 / NM_001297549.2; = p.F852I on NM_002911.4) | Missense Mutation (SNP) | VAF 113/241 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- VCAN | c.656G>A p.G219E | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF622 | c.1400A>G p.K467R | Missense Mutation (SNP) | VAF 59/104 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- C6orf136 | c.771T>C p.Y257= (on ENST00000376473 / NM_001109938.3; = p.Y123= on NM_145029.4) | Silent (SNP) | VAF 89/180 reads (49%) | called by muse, mutect2, varscan2
- CALCA | c.150G>T p.L50= | Silent (SNP) | VAF 29/57 reads (51%) | called by muse, mutect2, varscan2
- CFAP47 | c.5076T>C p.F1692= | Silent (SNP) | VAF 37/37 reads (100%) | called by muse, mutect2, varscan2
- DHCR24 | c.771C>T p.H257= | Silent (SNP) | VAF 96/168 reads (57%) | catalogued as rs1258262424, COSV64874213; called by muse, mutect2, varscan2
- HDX | c.1177T>C p.L393= | Silent (SNP) | VAF 31/32 reads (97%) | called by muse, mutect2, varscan2
- ITIH1 | c.2268C>T p.G756= | Silent (SNP) | VAF 142/284 reads (50%) | catalogued as COSV56254569, COSV99835610; called by muse, mutect2, varscan2
- NR2F1 | c.975C>T p.I325= | Silent (SNP) | VAF 61/144 reads (42%) | catalogued as COSV59069188; called by muse, mutect2, varscan2
- RGL2 | c.1656C>T p.P552= | Silent (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- TAF4 | c.1971G>C p.L657= | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV53338979; called by muse, mutect2
- VSIG10 | c.414C>T p.N138= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as rs755227482, COSV63654768; called by muse, mutect2, varscan2
- ZSCAN23 | c.531A>C p.R177= | Silent (SNP) | VAF 39/102 reads (38%) | called by muse, mutect2, varscan2
- ACHE | chr7:100896671 G>C | 5'Flank (SNP) | VAF 90/195 reads (46%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.*1375G>A | 3'UTR (SNP) | VAF 101/200 reads (51%) | catalogued as rs147186157; called by muse, mutect2, varscan2
- ADGRL3 | c.3944-1909A>C | Intron (SNP) | VAF 26/49 reads (53%) | catalogued as rs1560577074; called by muse, mutect2, varscan2
- AIPL1 | c.*1136G>T | 3'UTR (SNP) | VAF 9/17 reads (53%) | catalogued as rs1403570143; called by muse, mutect2, varscan2
- BPIFB1 | c.*31G>C | 3'UTR (SNP) | VAF 92/204 reads (45%) | called by muse, mutect2, varscan2
- CASK | chrX:41516965 T>C | 3'Flank (SNP) | VAF 13/13 reads (100%) | called by muse, mutect2, varscan2
- CFAP20DC | c.*197G>C | 3'UTR (SNP) | VAF 42/72 reads (58%) | called by muse, mutect2, varscan2
- CHCHD2P9 | n.160G>T | RNA (SNP) | VAF 9/18 reads (50%) | catalogued as rs367764738; called by muse, mutect2
- CHD3 | c.*600G>A | 3'UTR (SNP) | VAF 37/85 reads (44%) | called by muse, mutect2, varscan2
- COA1 | c.-38-793C>T | Intron (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- CSNK1A1 | c.-211A>G | 5'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- FAM167A | c.*332G>T | 3'UTR (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- FFAR4 | c.*2308T>C | 3'UTR (SNP) | VAF 46/85 reads (54%) | called by muse, mutect2, varscan2
- HYPK | c.-478G>T | 5'UTR (SNP) | VAF 205/402 reads (51%) | called by muse, mutect2, varscan2
- LTB | c.208+91T>G | Intron (SNP) | VAF 44/95 reads (46%) | called by muse, mutect2, varscan2
- LYSMD3 | c.*2403C>A | 3'UTR (SNP) | VAF 80/182 reads (44%) | called by muse, varscan2
- NPAT | c.*811G>A | 3'UTR (SNP) | VAF 57/120 reads (48%) | called by muse, mutect2, varscan2
- PAX6 | c.11-326T>C | Intron (SNP) | VAF 124/257 reads (48%) | called by muse, mutect2, varscan2
- PCSK2 | c.*1792A>T | 3'UTR (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- PKHD1 | c.*3119G>A | 3'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- PLP1 | c.*1428G>A | 3'UTR (SNP) | VAF 71/72 reads (99%) | called by muse, mutect2, varscan2
- RAB30 | c.*8965T>A | 3'UTR (SNP) | VAF 21/41 reads (51%) | catalogued as rs1447100524; called by muse, mutect2, varscan2
- RPL5 | c.*20T>C | 3'UTR (SNP) | VAF 80/159 reads (50%) | catalogued as rs747781113; called by muse, mutect2, varscan2
- SLC12A9 | c.1219-145G>A | Intron (SNP) | VAF 12/133 reads (9%) | catalogued as rs745820342; called by muse, mutect2
- SPRR2C | n.6T>A | RNA (SNP) | VAF 43/116 reads (37%) | called by muse, mutect2, varscan2
- SPSB2 | c.664+427T>A | Intron (SNP) | VAF 56/120 reads (47%) | called by muse, mutect2, varscan2
- SPSB2 | c.664+371T>C | Intron (SNP) | VAF 94/178 reads (53%) | called by muse, mutect2, varscan2
- TBK1 | c.*545C>T | 3'UTR (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- TEAD1 | c.*4731A>G | 3'UTR (SNP) | VAF 43/96 reads (45%) | catalogued as rs751916245; called by muse, mutect2, varscan2
- TNRC18 | c.6148-36C>T | Intron (SNP) | VAF 26/50 reads (52%) | catalogued as rs1367554297, COSV100079216; called by muse, mutect2, varscan2
- TUSC3 | c.*804C>A | 3'UTR (SNP) | VAF 67/130 reads (52%) | called by muse, mutect2, varscan2
- VGLL3 | c.*4188T>G | 3'UTR (SNP) | VAF 54/118 reads (46%) | called by muse, mutect2, varscan2
- XG | c.*811T>G | 3'UTR (SNP) | VAF 85/86 reads (99%) | called by muse, mutect2, varscan2
- ZFHX4 | c.*1320T>G | 3'UTR (SNP) | VAF 64/126 reads (51%) | called by muse, mutect2, varscan2
- ZFHX4 | c.*1453G>C | 3'UTR (SNP) | VAF 88/174 reads (51%) | called by muse, mutect2, varscan2
